HCMI case HCM-SANG-0294-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/dd73ec51-8600-4f56-8591-92fd11c3cc92

Demographics
Sex at birth: male; Days to birth: -23,923 days (65.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Lower third of esophagus; Classification of tumor: primary; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Esophageal columnar metaplasia present: Yes; Gastric esophageal junction involvement: No; Goblet cells columnar mucosa present: Yes; Uicc clinical stage: Stage IIIC; Uicc pathologic m: M0; Uicc pathologic n: N2; Uicc pathologic stage: Stage IIIB; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Cisplatin + Trastuzumab; Treatment intent type: Neoadjuvant; Days to treatment start: 125 days.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Reflux treatment type: Proton Pump Inhibitors; Risk factor treatment: Yes; Risk factors: GERD.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol intensity: Non-Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (7 samples)
- Sample HCM-SANG-0294-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-SANG-0294-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HCM-SANG-0294-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0294-C15-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0294-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0294-C15-85A-01D-A80T-32, HCM-SANG-0294-C15-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
